Surgical pathology report (de-identified scan), TCGA case TCGA-L9-A5IP, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Candler, specimen TCGA-L9-A5IP-01A (Primary Tumor).

[page 1 of 4]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED] Specimen Inquiry

PATIENT: [REDACTED]	ACCT #: [REDACTED]	LOC: [REDACTED]	U #: [REDACTED]
REG DR: [REDACTED]	AGE/SX: [REDACTED]	ROOM: [REDACTED]	REG: [REDACTED]
	DOB: [REDACTED]	BED: [REDACTED]	DIS: [REDACTED]
	STATUS: [REDACTED]	TLOC: [REDACTED]	

SPEC #: [REDACTED] PERFORMED AT [REDACTED]
TIME IN FORMALIN: 8:57 hrs.

CLINICAL INFORMATION:

Pre-Op Diagnosis: Right lung hilar mass; lung CA
Remarks:
Specimen(s): A. Right lung
B. Right level 4
C. Level 10 right lymph node

MICROSCOPIC DIAGNOSIS

- A. LUNG, RIGHT, PNEUMONECTOMY:
- INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA INVOLVING RIGHT UPPER LOBE, LOWER LOBE, AND MAINSTEM BRONCHUS MEASURING 5.5 CM
- INVOLVEMENT OF PERIHILAR NODAL AND SOFT TISSUE WITH PERINEURAL AND VASCULAR INVASION
- AT LEAST 2 OF 3 HILAR LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA
- 3 OF 3 PERIBRONCHIAL LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA
- BRONCHIAL MARGIN POSITIVE MICROSCOPICALLY FOR CARCINOMA AND GROSSLY MEASURES 1.5 CM FROM ENDOBRONCHIAL COMPONENT
- CLIPPED VASCULAR MARGIN POSITIVE FOR CARCINOMA WITHIN SOFT TISSUE AND BLOOD
- RESPIRATORY BRONCHIOLITIS AND RIGHT MIDDLE LOBE ATELECTASIS
- B. RIGHT LEVEL 4 LYMPH NODE:
- LYMPH NODE TISSUE FOCALLY POSITIVE FOR METASTATIC ADENOCARCINOMA WITH PERINODAL LYMPHATIC INVASION PRESENT
- C. RIGHT LEVEL 10 LYMPH NODE:
- 3 OF 3 LYMPH NODES POSITIVE FOR METASTATIC ADENOCARCINOMA WITH EXTRANODAL CAPSULAR EXTENSION PRESENT

COMMENT(S)

The patient has a large endobronchial mass demonstrating a poorly differentiated adenocarcinoma with extensive tumor necrosis where the epicenter appears to be at the junction of the right mainstem and upper lobe bronchus with extension along the lower lobe bronchus. The firm nodal mass which was adherent to the bronchus, when removed, demonstrates apparent matted lymph node tissue involved by metastatic adenocarcinoma with extensive involvement of the adjacent soft tissue as well as with perineural and angiolymphatic invasion present. Tumor involves the surface in this area. Clinical correlation is recommended to ascertain whether there was direct involvement of other mediastinal structures in this area. The bronchial margin does demonstrate carcinoma

** CONTINUED ON NEXT PAGE **

ICD-O-3
Adenocarcinoma 8140/3
Site: 1
Path: ② Lung, upper and lower lobes C34.8
CCF: ② Lung, upper lobe C34.1
01/16/13

[page 2 of 4]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 2

Specimen Inquiry

SPEC #:

PATIENT:

(Continued)

COMMENT(S)

(Continued)

present within the peribronchial soft tissue. Adenocarcinoma is also demonstrated in the sections obtained of the clipped vascular margins. In other sections, malignant cells penetrate the adventitia of the pulmonary artery without definitive muscle wall invasion identified. Immunohistochemical stains were performed on the previous bronchoscopic biopsy. The tumor in the bronchoscopic biopsy was found to be positive for CK7 and negative for TTF1, CK5/6 and P63. These stains will not be repeated unless otherwise requested.

CAP Protocol for the Examination of Specimens From Patients With Primary Non-Small Cell Carcinoma, Small Cell Carcinoma, or Carcinoid Tumor of the Lung
Based on AJCC/UICC TNM, 7th edition

Specimen:	Lung
Procedure:	Pneumonectomy
Specimen Integrity:	Intact
Specimen Laterality:	Right
Tumor Site:	Other: endobronchial hilar mass involving right upper lobe, mainstem, and right lower lobe
Tumor Size:	Greatest dimension: 5.5 cm
Tumor Focality:	Unifocal
Histologic Type:	Adenocarcinoma
Histologic Grade:	Grade 3: poorly differentiated
Visceral Pleural Invasion:	Not identified
Tumor Extension:	Tumor in the main bronchus <2 cm distal to the carina
Margins:	Bronchial: Involved by invasive carcinoma Vascular: Involved by invasive carcinoma Other attached tissue margin: Not applicable (none designated)
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Present
Pathologic Staging:	Primary Tumor: pT3 Regional Lymph Nodes: pN2 Number examined: At least 10 Number involved: 9 Distant Metastasis: Not applicable

GROSS DESCRIPTION:

A. Received fresh labeled with the patient's name and "right lung" with request for tissue banking is a right lobectomy specimen which weighs 574 grams and measures 30 x 15 x 9 cm in the inflated state. The right middle lobe is somewhat collapsed compared to the upper and lower lobes. The middle lobe measures 11 x 6 x 2 cm. The bronchial margin measures 2 cm in diameter. Blue ink is applied to this margin. An endobronchial mass is visualized through the bronchial lumen. The mass lies 1.5 cm from the bronchial margin. The bronchial margin is separated from the specimen and submitted in block A1. The clipped vascular margins are identified and are submitted in block A2. A firm mass is palpated in the hilar aspect at the junction between the upper and lower lobes. The pleura is retracted at the junction of the three lobes at the peripheral aspect. Blue ink is applied

** CONTINUED ON NEXT PAGE **

[page 3 of 4]
RUN DATE:

PAGE 3

RUN TIME:

Specimen Inquiry

RUN USER:

Lab Database:

SPEC #:

PATIENT:

(Continued)

GROSS DESCRIPTION: (Continued)

to this area. There is a firm hilar mass which when sectioned may represent a pathologic lymph node or lymph node tissue involved by direct extension. This area is adherent to the bronchial wall and when removed measures 4.5 x 2.5 x 1.5 cm. Two other hilar lymph nodes are identified, 2 and 2.5 cm in greatest dimension. The lung is sectioned longitudinally along the axis of the bronchial margin revealing a right upper lobe mass extending into the main bronchus with lateral extension along the lower lobe bronchus measuring 5.5 x 3 x 5.5 cm. There is direct extension into peribronchial lymph nodes. There is purulent material which fill the distal bronchi and necrotic material is noted within step sections of the tumor. There is a small skip area along the lower lobe bronchus where a separate submucosal mass is noted measuring 1 cm. This may just represent direct extension around the bronchus. The lower lobe has a yellowish-brown color possibly representing obstructive pneumonia. A portion of non-necrotic tumor is provided to the tissue bank coordinator with a weight of 230 mg noted. No other discrete masses are identified. Additional sections are submitted as follows:

- A3 - one hilar lymph node bisected and totally submitted
- A4.5 - one hilar lymph node bisected and totally submitted
- A6 - sections of largest hilar mass
- A7 - sections of smaller grossly positive peribronchial lymph nodes
- A8.9 - sections of endobronchial extension
- A10 - longitudinal sections of tumor and right upper lobe bronchus
- A11 - section demonstrating separate or adjacent submucosal polypoid mass
- A12 - tumor
- A13 - section of tumor and inked pleural surface
- A14 - right upper lobe apex
- A15 - right lower lobe base
- A16 - right middle lobe

B. In formalin labeled with the patient's name and "right level 4" is several irregular portions of reddish-tan tissue which measure together 2 x 1.5 x 0.5 cm. The larger is bisected and submitted with two smaller fragments in block B.

C. In formalin labeled with the patient's name and "right level 10 lymph node" is three irregular portions of reddish-brown soft tissue measuring 1.5, 2, 2.5 cm in greatest dimension. There is also a separate 5 mm fragment of similar tissue. The smaller fragment and the smallest portion is sectioned and submitted in block C1. The next to largest portion is sectioned and submitted in block C2. The largest portion is serially sectioned and in doing so, a 5 mm gray nodule is noted consistent with metastasis. Representative sections of this portion are submitted in block C3.

INTRAOPERATIVE CONSULTATION:

A. RIGHT LUNG:

- TISSUE PROCESSED FOR TISSUE BANK WITH TUMOR AND NON-TUMOROUS TISSUE PROVIDED TO TISSUE BANK COORDINATOR

** CONTINUED ON NEXT PAGE **

[page 4 of 4]
RUN DATE:
RUN TIME:
RUN USER:

Specimen Inquiry

SPEC #

PATIENT #

(Continued)

PHOTO DOCUMENTATION

Signed ____ (signature on file) ____

** END OF REPORT **

Asynchronous Primary		/

Source: NCI Genomic Data Commons file d34ee421-1cc5-497e-abb1-8fbfd04468e4 (TCGA-L9-A5IP.0C79A75F-E3B3-4984-8406-2532E4A68D96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).